Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A3U7, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A3U7-01A (Primary Tumor).

[page 1 of 2]
DEPARTMENT OF PATHOLOGY

SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]

CC:
Patient Address: [REDACTED]

....

Specimens Submitted:
1: SP: Radical resection adductor compartment sarcoma

DIAGNOSIS:
1. SOFT TISSUE, RIGHT THIGH, ADDUCTOR COMPARTMENT; RADICAL RESECTION:
- HIGH GRADE LEIOMYOSARCOMA, INVOLVING SUBCUTANEOUS TISSUE.
- TUMOR NECROSIS AND CYSTIC HEMORRHAGIC CHANGES ARE PRESENT, COMPRISING 10-20% OF THE MASS.
- TUMOR SIZE: 9.2 x 7.5 x 6.3 CM.
- SURGICAL MARGINS ARE FREE OF TUMOR. HOWEVER, TUMOR IS CLOSE (0.15 CM) TO THE DEEP MARGIN.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:		
Result	Special Stain	Comment
	RECUT	

Gross Description:

1) The specimen is labeled "radical resection adductor compartment" and consists of a 20 x 17 x 6.5 cm oriented skeletal muscle with an overlying grossly unremarkable tan skin ellipse (22.3 x 12.5 cm). As per requisition, a short suture marks the superior margin and a long suture marks the lateral margin. There is a 9.2 x 7.5 x 6.3 cm fairly well circumscribed white pink partially solid and partially cystic fleshy mass. It is located 0.1 cm from the deep margin, 3.5 cm from the superior margin, 6.0 cm from the inferior margin, 6.5 cm from the lateral margin and 12.0 cm from the medial margin. Representative sections are submitted, including a portion for TPS.

** Continued on next page **

1CD-0-3
leiomyosarcoma, NOS
8890/3
Site: thigh, subcutaneous tissue
C49.2
5-2-12
RO

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Accession

Page 2 of 2

Summary of sections:

SM superior margin
IM inferior margin
LM lateral margin
MM medial margin
T tumor (including deep margin 1-5)
S skin

Summary of Sections:

Part 1: SP: Radical resection adductor compartment sarcoma

Block	Sect.	Site	PCs	
1		{not entered}		1
1		IM	1	
1		LM	1	
1		MM	1	
1		S	1	
1		SM	1	
8		T	8	

** End of Report **

Source: NCI Genomic Data Commons file 69368796-b943-420b-95ee-c137b56d5a04 (TCGA-DX-A3U7.AC9C8C59-595E-4145-ADC4-86330B76D546.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).